CCDI case PBCWPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/b6fe156f-ac79-483a-aa87-54b25989608c

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample 0E1P18: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1P19: Tissue type: Tumor; Specimen type: Solid Tissue.
